Gene-level copy-number profile of tumor specimen TCGA-AJ-A3EJ-01A from TCGA case TCGA-AJ-A3EJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 74.8 years (27,317 days).
Specimen TCGA-AJ-A3EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.ee8de32e-390b-4068-bbbc-e3d2a11f3c48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3EJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3145d6e0-c88e-4679-a22b-136942d2f91f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 308; copy number 2: 14,065; copy number 3: 17,745; copy number 4: 15,225; copy number 5: 11,116; copy number 6: 1,016; copy number 7: 207; copy number 8: 114; copy number 9: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3EJ-01A-11D-A19X-01): tumor purity 0.63, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 333 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,415,825–30,421,108, 1 gene, copy number 7: AL161638.1.
- chr1:117,060,326–117,528,872, 10 genes, copy number 7 (within-gene range 5–7): TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2.
- chr1:151,279,678–151,853,712, 41 genes, copy number 7 (within-gene range 5–7): ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5.
- chr2:98,444,854–99,154,964, 10 genes, copy number 7 (within-gene range 4–7): INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10.
- chr2:175,072,250–175,463,180, 8 genes, copy number 9 (within-gene range 4–9): ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1.
- chr2:207,687,960–208,057,745, 11 genes, copy number 7: Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17.
- chr2:232,343,116–232,583,644, 18 genes, copy number 8 (within-gene range 6–8): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG, TIGD1, MIR5001, EIF4E2.
- chr6:37,170,152–37,699,306, 16 genes, copy number 7: PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr7:116,238,260–116,499,465, 1 gene, copy number 7 (within-gene range 4–7): AC002066.1.
- chr7:116,287,380–117,264,888, 34 genes, copy number 7 (within-gene range 4–7): CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6.
- chr8:22,679,013–22,798,616, 4 genes, copy number 9: AC105046.1, EGR3, AC055854.1, AC105046.2.
- chr8:54,330,687–54,479,963, 7 genes, copy number 7: RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 7: SEC11B.
- chr10:10,369,809–12,043,170, 22 genes, copy number 7 (within-gene range 4–7): CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P.
- chr10:59,578,467–59,960,913, 5 genes, copy number 7: AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,140,877, 3 genes, copy number 7: AL592430.1, Y_RNA, AL592430.2.
- chr11:14,262,846–14,643,635, 7 genes, copy number 7 (within-gene range 2–7): SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1.
- chr12:111,766,887–113,098,028, 35 genes, copy number 8 (within-gene range 3–8): ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1.
- chr19:12,675,717–13,158,788, 52 genes, copy number 8: DHPS, AC010422.2, GNG14, FBXW9, AC018761.4, TNPO2, SNORD41, AC018761.1, TRIR, GET3, BEST2, HOOK2, AC018761.3, MIR5684, JUNB, PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.
- chr20:4,590,993–4,823,608, 8 genes, copy number 8: AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2.
- chr20:4,868,984–4,869,118, 1 gene, copy number 8: AL389886.1.
- chr20:34,132,270–34,872,856, 26 genes, copy number 7: AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7.
- chr20:46,540,946–47,188,844, 12 genes, copy number 7 (within-gene range 5–7): OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1.

Autosomal genes at a single copy (total copy number 1): 308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
